Somatic mutation profile of tumor specimen C3L-02208-01 (aliquot CPT0171890011) from CPTAC case C3L-02208, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Renal cell carcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 69.0 years (25,198 days).
Specimen C3L-02208-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6d2d1ce7-4502-4262-bb33-b136514675de.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-02208-31 (Blood Derived Normal), aliquot CPT0167350002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4f0a9d43-7933-4c09-b107-dfc3ab220382

The open-access MAF lists 118 somatic variants for this specimen: 81 protein-altering or splice-affecting, 28 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 61, Silent 28, Frame Shift Del 9, 5'UTR 4, Nonsense Mutation 4, Splice Site 4, Intron 2, 5'Flank 1, 3'UTR 1, RNA 1, Nonstop Mutation 1, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- VHL | c.464-1G>C p.X155_splice | Splice Site (SNP) | VAF 127/428 reads (30%) | hotspot (GDC flag); catalogued as rs5030817, CS071276, CS941547, CS961706, COSV56542304, COSV56544494, COSV56544554, COSV56553901; ClinVar: pathogenic; called by muse, mutect2, varscan2
- AADAT | c.847A>G p.R283G | Missense Mutation (SNP) | VAF 38/201 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.782); catalogued as rs773871959; called by muse, mutect2, varscan2
- AGAP6 | c.1233G>T p.W411C (on ENST00000374056 / NM_001365867.1; = p.W434C on NM_001077665.2) | Missense Mutation (SNP) | VAF 106/482 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100929041; called by mutect2, varscan2
- ALDH1A2 | c.549C>G p.I183M | Missense Mutation (SNP) | VAF 56/368 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV51084881, COSV51091453; called by muse, mutect2, varscan2
- AXL | c.1889G>T p.S630I (on ENST00000301178 / NM_021913.5; = p.S621I on NM_001699.6) | Missense Mutation (SNP) | VAF 15/188 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.662); catalogued as COSV56575950; called by muse, mutect2
- CACNA1I | c.5140G>A p.V1714M | Missense Mutation (SNP) | VAF 24/347 reads (7%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as COSV60807377; called by muse, mutect2
- CEP126 | c.600G>A p.M200I | Missense Mutation (SNP) | VAF 53/259 reads (20%) | SIFT tolerated (0.26); PolyPhen benign (0.073); catalogued as COSV54826527; called by muse, mutect2, varscan2
- CNOT3 | c.178G>A p.D60N | Missense Mutation (SNP) | VAF 40/201 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55364202; called by muse, mutect2, varscan2
- CTBP2 | c.170T>C p.V57A | Missense Mutation (SNP) | VAF 45/223 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.287); catalogued as COSV58332379; called by muse, mutect2, varscan2
- DIP2B | c.2043C>G p.I681M | Missense Mutation (SNP) | VAF 47/224 reads (21%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.513); catalogued as rs1480179847; called by muse, mutect2, varscan2
- DMKN | c.586G>C p.G196R | Missense Mutation (SNP) | VAF 62/356 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV60087094; called by muse, mutect2, varscan2
- ELAVL3 | c.1009G>A p.E337K | Missense Mutation (SNP) | VAF 55/290 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV52951635; called by muse, mutect2, varscan2
- HECW1 | c.1954C>T p.P652S | Missense Mutation (SNP) | VAF 38/153 reads (25%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.036); catalogued as rs772293426; called by muse, mutect2, varscan2
- KMT2C | c.2058del p.K686Nfs*2 | Frame Shift Del (DEL) | VAF 33/165 reads (20%) | catalogued as COSV100070068; called by mutect2, pindel, varscan2
- LTBP4 | c.1417C>A p.R473S (on ENST00000308370 / NM_001042544.1; = p.R436S on NM_003573.2) | Missense Mutation (SNP) | VAF 67/304 reads (22%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.759); catalogued as COSV99180573, COSV99192998; called by muse, mutect2, varscan2
- NPHS1 | c.3084del p.T1029Pfs*114 | Frame Shift Del (DEL) | VAF 93/400 reads (23%) | catalogued as COSV100800224; called by mutect2, pindel, varscan2
- OR3A2 | c.197C>T p.A66V | Missense Mutation (SNP) | VAF 17/139 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as rs1451816694; called by muse, mutect2, varscan2
- POLR3B | c.1009G>T p.V337L | Missense Mutation (SNP) | VAF 22/225 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs747242779; called by muse, mutect2
- PSG11 | c.772G>A p.D258N | Missense Mutation (SNP) | VAF 35/231 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.067); catalogued as rs745836316, COSV60454820, COSV60457274; called by muse, mutect2, varscan2
- REPIN1 | c.340C>A p.L114M | Missense Mutation (SNP) | VAF 130/445 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.201); catalogued as COSV101262581; called by muse, mutect2, varscan2
- SLC39A13 | c.410G>C p.S137T | Missense Mutation (SNP) | VAF 86/417 reads (21%) | SIFT tolerated (0.49); PolyPhen benign (0.001); catalogued as rs1419691842; called by muse, mutect2, varscan2
- SMAD4 | c.274C>T p.H92Y | Missense Mutation (SNP) | VAF 52/432 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61691170; called by muse, mutect2, varscan2
- TIAM1 | c.3995G>A p.R1332Q | Missense Mutation (SNP) | VAF 24/348 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV54562275, COSV99740368; called by muse, mutect2
- TPTE | c.905T>C p.I302T (on ENST00000618007 / NM_199261.4; = p.I284T on NM_199259.4) | Missense Mutation (SNP) | VAF 18/364 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.484); catalogued as rs753268180; called by muse, mutect2
- ZFC3H1 | c.3187A>G p.T1063A | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT tolerated (0.25); PolyPhen benign (0.1); catalogued as rs757974811, COSV66430099; called by muse, mutect2, varscan2
- ZSCAN5C | c.1324T>C p.C442R | Missense Mutation (SNP) | VAF 29/176 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs776702821; called by muse, mutect2, varscan2
- ADD3 | c.1323C>G p.N441K | Missense Mutation (SNP) | VAF 21/307 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- AGAP6 | c.1237_1242dup p.Q413_A414dup (on ENST00000374056 / NM_001365867.1; = p.Q436_A437dup on NM_001077665.2) | In Frame Ins (INS) | VAF 84/464 reads (18%) | called by mutect2, varscan2
- ANAPC4 | c.1197G>T p.K399N | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- BCL6B | c.653C>G p.S218C | Missense Mutation (SNP) | VAF 81/388 reads (21%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.501); called by muse, mutect2, varscan2
- CAPRIN1 | c.361C>T p.Q121* | Nonsense Mutation (SNP) | VAF 12/94 reads (13%) | called by muse, mutect2, varscan2
- CLPSL1 | c.214C>G p.Q72E | Missense Mutation (SNP) | VAF 39/332 reads (12%) | SIFT tolerated (0.45); PolyPhen benign (0.214); called by muse, mutect2, varscan2
- CPEB4 | c.505A>G p.S169G | Missense Mutation (SNP) | VAF 24/238 reads (10%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.055); called by muse, mutect2
- CPT1B | c.765C>G p.N255K | Missense Mutation (SNP) | VAF 70/276 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.768); called by muse, mutect2, varscan2
- DDC | c.697G>T p.G233C | Missense Mutation (SNP) | VAF 52/247 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DDN | c.203A>G p.N68S | Missense Mutation (SNP) | VAF 41/213 reads (19%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- DDR1 | c.2376T>A p.Y792* (on ENST00000324771; = p.Y755* on NM_001954.4) | Nonsense Mutation (SNP) | VAF 50/213 reads (23%) | called by muse, mutect2, varscan2
- DIDO1 | c.2556del p.C853Vfs*31 | Frame Shift Del (DEL) | VAF 39/195 reads (20%) | called by mutect2, pindel, varscan2
- DNAH14 | c.3512C>A p.T1171N (on ENST00000445597; = p.T1555N on NM_001367479.1) | Missense Mutation (SNP) | VAF 28/158 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ELN | c.334C>T p.L112F | Missense Mutation (SNP) | VAF 177/778 reads (23%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.833); called by muse, mutect2, varscan2
- EP400 | c.5586G>T p.G1862= | Splice Region (SNP) | VAF 26/220 reads (12%) | called by muse, mutect2, varscan2
- ESRRA | c.632C>G p.A211G | Missense Mutation (SNP) | VAF 64/223 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- FAM217B | c.391C>A p.P131T | Missense Mutation (SNP) | VAF 53/238 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.177); called by muse, mutect2, varscan2
- FGD6 | c.1165G>C p.E389Q | Missense Mutation (SNP) | VAF 40/176 reads (23%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- IGKV1D-42 | c.56_68del p.G19Afs*4 | Frame Shift Del (DEL) | VAF 28/164 reads (17%) | called by mutect2, pindel, varscan2
- ITGB3 | c.787G>T p.G263C | Missense Mutation (SNP) | VAF 71/251 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KCNN1 | c.1459A>T p.S487C | Missense Mutation (SNP) | VAF 66/287 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.246); called by muse, mutect2, varscan2
- KCTD7 | c.420G>T p.Q140H | Missense Mutation (SNP) | VAF 118/450 reads (26%) | SIFT tolerated (0.5); PolyPhen benign (0.063); called by muse, mutect2, varscan2
- LARP4 | c.1121+1G>C p.X374_splice | Splice Site (SNP) | VAF 41/156 reads (26%) | called by muse, mutect2, varscan2
- LGALS14 | c.344G>T p.R115L | Missense Mutation (SNP) | VAF 24/281 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.864); called by muse, mutect2
- LRRK2 | c.6455T>G p.V2152G | Missense Mutation (SNP) | VAF 20/258 reads (8%) | SIFT tolerated (0.4); PolyPhen benign (0); called by muse, mutect2
- MED13L | c.4124A>C p.E1375A | Missense Mutation (SNP) | VAF 134/511 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- MPHOSPH10 | c.1069A>T p.K357* | Nonsense Mutation (SNP) | VAF 34/131 reads (26%) | called by muse, mutect2, varscan2
- MYH1 | c.2431del p.R811Efs*16 | Frame Shift Del (DEL) | VAF 51/234 reads (22%) | called by mutect2, pindel, varscan2
- NFATC1 | c.1693C>G p.R565G | Missense Mutation (SNP) | VAF 33/250 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NPSR1 | c.1114T>C p.*372Qext*8 | Nonstop Mutation (SNP) | VAF 18/174 reads (10%) | called by muse, mutect2
- NXPH1 | c.659A>G p.Q220R | Missense Mutation (SNP) | VAF 58/248 reads (23%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- OR5M1 | c.883A>T p.T295S | Missense Mutation (SNP) | VAF 22/90 reads (24%) | SIFT deleterious (0); PolyPhen benign (0); called by muse, mutect2
- PAX1 | c.871T>C p.S291P | Missense Mutation (SNP) | VAF 44/254 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); called by muse, mutect2, varscan2
- PDZD8 | c.1105T>G p.L369V | Missense Mutation (SNP) | VAF 30/120 reads (25%) | SIFT tolerated (0.63); PolyPhen benign (0.017); called by muse, mutect2
- PDZRN4 | c.56A>C p.K19T | Missense Mutation (SNP) | VAF 101/584 reads (17%) | SIFT tolerated, low confidence (0.21); called by muse, mutect2, varscan2
- PIP4K2A | c.944A>C p.D315A | Missense Mutation (SNP) | VAF 32/151 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.612); called by muse, mutect2, varscan2
- PNLIP | c.148G>C p.D50H | Missense Mutation (SNP) | VAF 64/230 reads (28%) | SIFT tolerated (0.16); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- PRAMEF11 | c.239del p.F80Sfs*64 | Frame Shift Del (DEL) | VAF 96/620 reads (15%) | called by mutect2, pindel, varscan2
- PSMC1 | c.1189-1G>A p.X397_splice | Splice Site (SNP) | VAF 10/77 reads (13%) | called by muse, mutect2, varscan2
- PTPRQ | c.1884G>T p.L628F (on ENST00000616559; = p.L586F on NM_001145026.2) | Missense Mutation (SNP) | VAF 29/144 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PUSL1 | c.365G>T p.R122L | Missense Mutation (SNP) | VAF 25/250 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- RNF167 | c.166-9_173del p.X56_splice | Splice Site (DEL) | VAF 13/68 reads (19%) | called by mutect2, pindel, varscan2
- RP1 | c.3142G>T p.E1048* | Nonsense Mutation (SNP) | VAF 31/194 reads (16%) | called by muse, mutect2, varscan2
- RXFP1 | c.1534A>C p.I512L | Missense Mutation (SNP) | VAF 32/131 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- SHROOM2 | c.3476del p.L1159Rfs*23 | Frame Shift Del (DEL) | VAF 85/224 reads (38%) | called by mutect2, pindel, varscan2
- SMCO2 | c.337T>G p.F113V | Missense Mutation (SNP) | VAF 32/182 reads (18%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.719); called by muse, mutect2, varscan2
- SORD | c.565T>G p.L189V | Missense Mutation (SNP) | VAF 72/328 reads (22%) | SIFT tolerated (0.13); PolyPhen benign (0.082); called by muse, mutect2, varscan2
- ST7 | c.379A>T p.R127W | Missense Mutation (SNP) | VAF 59/297 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- SULT1A1 | c.697A>C p.K233Q | Missense Mutation (SNP) | VAF 135/855 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.35); called by muse, mutect2, varscan2
- SVEP1 | c.9554A>T p.E3185V | Missense Mutation (SNP) | VAF 90/374 reads (24%) | SIFT tolerated (0.27); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- TIGD3 | c.494_497del p.K165Tfs*79 | Frame Shift Del (DEL) | VAF 50/406 reads (12%) | called by mutect2, pindel, varscan2
- TNRC18 | c.1794C>G p.D598E | Missense Mutation (SNP) | VAF 140/531 reads (26%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- TRRAP | c.8548T>G p.Y2850D (on ENST00000359863 / NM_001244580.1; = p.Y2832D on NM_003496.3) | Missense Mutation (SNP) | VAF 98/504 reads (19%) | SIFT tolerated (0.21); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- VPS16 | c.2030T>C p.L677P | Missense Mutation (SNP) | VAF 42/157 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ZNF10 | c.428del p.P143Qfs*5 | Frame Shift Del (DEL) | VAF 23/93 reads (25%) | called by mutect2, pindel, varscan2
- ABHD14A-ACY1 | c.747G>T p.V249= | Silent (SNP) | VAF 163/525 reads (31%) | called by muse, mutect2, varscan2
- CAMK4 | c.195G>A p.Q65= | Silent (SNP) | VAF 31/217 reads (14%) | called by muse, mutect2, varscan2
- CD163L1 | c.2121C>G p.V707= | Silent (SNP) | VAF 86/291 reads (30%) | called by muse, mutect2, varscan2
- CEP170B | c.963G>A p.Q321= (on ENST00000453495; = p.Q250= on NM_015005.3) | Silent (SNP) | VAF 51/336 reads (15%) | catalogued as rs757124762; called by muse, mutect2, varscan2
- CFAP46 | c.2091G>A p.P697= | Silent (SNP) | VAF 34/179 reads (19%) | catalogued as rs915562887; called by muse, mutect2, varscan2
- CLNK | c.45C>T p.N15= | Silent (SNP) | VAF 35/223 reads (16%) | catalogued as rs776932670, COSV57013235; called by muse, mutect2, varscan2
- COL11A2 | c.1194G>A p.E398= (on ENST00000341947 / NM_080680.3; = p.E291= on NM_080679.2) | Silent (SNP) | VAF 159/619 reads (26%) | called by muse, mutect2, varscan2
- DDC | c.990C>A p.P330= | Silent (SNP) | VAF 178/742 reads (24%) | called by muse, mutect2, varscan2
- DHX37 | c.366G>T p.G122= | Silent (SNP) | VAF 56/219 reads (26%) | called by muse, mutect2, varscan2
- DLGAP2 | c.321C>T p.C107= | Silent (SNP) | VAF 22/245 reads (9%) | catalogued as COSV101421522; called by muse, mutect2
- FGF3 | c.543C>T p.R181= | Silent (SNP) | VAF 33/224 reads (15%) | catalogued as COSV61925969; called by muse, mutect2, varscan2
- FNDC1 | c.2874G>A p.A958= | Silent (SNP) | VAF 47/261 reads (18%) | called by muse, mutect2, varscan2
- IFNA13 | c.471G>A p.E157= | Silent (SNP) | VAF 50/332 reads (15%) | called by muse, varscan2
- NEBL | c.135C>T p.C45= | Silent (SNP) | VAF 30/512 reads (6%) | catalogued as rs757156256; called by muse, mutect2
- PDCD6IP | c.2373C>A p.G791= | Silent (SNP) | VAF 89/333 reads (27%) | called by muse, mutect2, varscan2
- POTEB3 | c.6G>T p.V2= | Silent (SNP) | VAF 18/144 reads (13%) | called by mutect2, varscan2
- RBM14 | c.1437A>C p.S479= | Silent (SNP) | VAF 12/100 reads (12%) | catalogued as rs1165251499; called by muse, mutect2, varscan2
- RPL11 | c.129A>G p.T43= (on ENST00000374550 / NM_001199802.1; = p.T44= on NM_000975.5) | Silent (SNP) | VAF 50/264 reads (19%) | called by muse, mutect2, varscan2
- SAMD4B | c.1521G>A p.L507= | Silent (SNP) | VAF 33/190 reads (17%) | called by muse, mutect2, varscan2
- SHANK1 | c.1182G>A p.E394= | Silent (SNP) | VAF 42/301 reads (14%) | called by muse, mutect2, varscan2
- SIRPA | c.1159C>T p.L387= | Silent (SNP) | VAF 78/407 reads (19%) | catalogued as rs920835595; called by muse, mutect2, varscan2
- SPEN | c.6996C>A p.R2332= | Silent (SNP) | VAF 34/191 reads (18%) | called by muse, mutect2, varscan2
- SRCAP | c.6582C>A p.G2194= | Silent (SNP) | VAF 37/161 reads (23%) | called by muse, mutect2, varscan2
- TAT | c.525G>A p.L175= | Silent (SNP) | VAF 18/442 reads (4%) | called by muse, mutect2
- TBC1D12 | c.354C>A p.R118= | Silent (SNP) | VAF 133/539 reads (25%) | called by muse, mutect2, varscan2
- TMEM170B | c.192T>C p.H64= | Silent (SNP) | VAF 30/506 reads (6%) | called by muse, mutect2
- TUBGCP2 | c.966G>A p.Q322= | Silent (SNP) | VAF 83/423 reads (20%) | called by muse, mutect2, varscan2
- UACA | c.2128T>C p.L710= | Silent (SNP) | VAF 16/140 reads (11%) | catalogued as rs148252688; called by muse, mutect2, varscan2
- ARCN1 | c.-31A>C | 5'UTR (SNP) | VAF 26/183 reads (14%) | called by muse, mutect2, varscan2
- DNAH14 | c.5584+5702del | Intron (DEL) | VAF 11/79 reads (14%) | called by mutect2, pindel, varscan2
- EFNB3 | c.-30del | 5'UTR (DEL) | VAF 8/41 reads (20%) | catalogued as rs770957727, COSV99872545; called by mutect2, pindel*, varscan2
- EYS | c.1767-7303G>A | Intron (SNP) | VAF 78/572 reads (14%) | catalogued as rs548605436; called by muse, mutect2, varscan2
- NLRC4 | c.-8C>A | 5'UTR (SNP) | VAF 11/107 reads (10%) | catalogued as COSV100707334; called by muse, mutect2, varscan2
- OR2M1P | n.281T>A | RNA (SNP) | VAF 48/312 reads (15%) | called by muse, mutect2, varscan2
- STMN2 | c.-39T>G | 5'UTR (SNP) | VAF 46/189 reads (24%) | called by muse, mutect2, varscan2
- TGFBR3 | c.*1185C>A | 3'UTR (SNP) | VAF 43/276 reads (16%) | called by muse, mutect2, varscan2
- TTLL10 | chr1:1169031 C>G | 5'Flank (SNP) | VAF 69/305 reads (23%) | called by muse, mutect2, varscan2
